HCMI case HCM-BROD-1181-C73 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cea2d371-6cd9-454b-a64b-be6c7b217134

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Dead; Days to death: 4,064 days (11.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73.9; Tissue or organ of origin: Thyroid gland; Classification of tumor: primary; Age at diagnosis: 61.3 years (22,379 days); Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Lenvatinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,974 days (10.9 years); Days to treatment end: 4,064 days (11.1 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Metastasis of the thyroid gland (histology not recorded by GDC). ICD-10 code: C78.6; Site of resection or biopsy: Pleura, NOS; Age at diagnosis: 61.3 years (22,379 days).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Lenvatinib; Treatment intent type: Maintenance Therapy; Days to treatment start: 3,222 days (8.8 years); Days to treatment end: 4,064 days (11.1 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 4,064 days (11.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 167 cm; BMI: 28.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1181-C73-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
